Somatic mutation profile of tumor specimen MP2PRT-PAPDPX-TMP1-A (aliquot MP2PRT-PAPDPX-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPDPX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,342 days).
Specimen MP2PRT-PAPDPX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08035231-1c0e-4e10-b792-5c5c9cc5c488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPDPX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPDPX-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36cd5a45-7c97-4a39-b5f9-beb5878a2d01

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1893T>A p.H631Q | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs752102488; called by muse, mutect2, varscan2
- AMY1B | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 62/363 reads (17%) | catalogued as rs760326172; called by muse, mutect2, varscan2
- CYP2C9 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 108/349 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs150435881, COSV53246052; called by muse, mutect2, varscan2
- DSCAM | c.5184G>A p.T1728= | Splice Region (SNP) | VAF 98/416 reads (24%) | catalogued as rs545172220; called by muse, mutect2, varscan2
- ELOVL4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765250776; called by muse, mutect2, varscan2
- FOXR2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 186/627 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs753191601; called by muse, mutect2, varscan2
- KCNG1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 172/371 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1317105849; called by muse, mutect2, varscan2
- PCSK2 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs754614068, COSV52730710; called by muse, mutect2, varscan2
- RBMXL3 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 197/751 reads (26%) | catalogued as rs1556558492; called by muse, mutect2, varscan2
- SETBP1 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs758128091, COSV56337985, COSV99954730; called by muse, mutect2, varscan2
- TMC3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs201212145; called by muse, mutect2, varscan2
- TNC | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 192/426 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); catalogued as rs1264066759, COSV100406229, COSV60787818; called by muse, mutect2, varscan2
- NUBP1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PDE4DIP | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- WNK3 | c.295A>T p.R99* | Nonsense Mutation (SNP) | VAF 147/493 reads (30%) | called by muse, mutect2, varscan2
- XRN1 | c.2335_2336insTC p.E779Vfs*5 | Frame Shift Ins (INS) | VAF 58/162 reads (36%) | called by mutect2, pindel, varscan2
- ZUP1 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- AMER3 | c.1272G>A p.E424= | Silent (SNP) | VAF 192/402 reads (48%) | called by muse, mutect2, varscan2
- C10orf90 | c.1980G>A p.P660= | Silent (SNP) | VAF 94/274 reads (34%) | catalogued as rs200783026, COSV52950179; called by muse, mutect2, varscan2
- GPR85 | c.387T>C p.Y129= | Silent (SNP) | VAF 154/321 reads (48%) | catalogued as rs1187742200; called by muse, mutect2, varscan2
- HOXA3 | c.282G>A p.P94= | Silent (SNP) | VAF 81/630 reads (13%) | catalogued as rs1412170236; called by muse, mutect2, varscan2
- TKTL1 | c.231C>T p.N77= | Silent (SNP) | VAF 107/361 reads (30%) | catalogued as rs938208645; called by muse, mutect2, varscan2
- TOR1A | c.690C>T p.D230= | Silent (SNP) | VAF 131/300 reads (44%) | called by muse, mutect2, varscan2
- ZNF254 | c.240G>A p.V80= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs751769324; called by muse, mutect2, varscan2
- ELP4 | c.1146+64606T>C | Intron (SNP) | VAF 67/159 reads (42%) | called by muse, mutect2, varscan2
- OLFM2 | c.*309_*310dup | 3'UTR (INS) | VAF 75/205 reads (37%) | catalogued as rs1019629866; called by mutect2, varscan2
